Somatic mutation profile of tumor specimen 0DZEH4 from CCDI case PBCTUP, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 3.1 years (1,127 days).
Specimen 0DZEH4: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b0c636b4-0a25-4057-a56c-773b19e37565.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DZEH2 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/59959cf9-903c-4516-a6eb-38c87589e0df

The open-access MAF lists 47 somatic variants for this specimen: 30 protein-altering or splice-affecting, 9 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 9, Intron 5, Nonsense Mutation 3, Splice Region 1, 3'UTR 1, 5'Flank 1, Splice Site 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CENPBD1 | c.468G>T p.M156I | Missense Mutation (SNP) | VAF 252/815 reads (31%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV51918003; called by muse, mutect2
- CTC1 | c.3170G>A p.R1057H | Missense Mutation (SNP) | VAF 205/386 reads (53%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs776956576, COSV100236422; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DSCAM | c.1430G>A p.R477Q | Missense Mutation (SNP) | VAF 237/620 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs1156542414, COSV101259763; called by muse, mutect2, varscan2
- MUC5B | c.14290G>T p.V4764F | Missense Mutation (SNP) | VAF 333/1125 reads (30%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.003); catalogued as rs778650701, COSV71591114; called by muse, mutect2, varscan2
- NEDD4 | c.2906C>A p.A969E (on ENST00000508342 / NM_001284338.1; = p.A550E on NM_006154.4) | Missense Mutation (SNP) | VAF 128/419 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.01); catalogued as rs780226262; called by muse, mutect2, varscan2
- NOTCH1 | c.5048G>A p.R1683Q | Missense Mutation (SNP) | VAF 357/862 reads (41%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV53082071; called by muse, mutect2
- PCDHAC1 | c.1491G>T p.L497F | Missense Mutation (SNP) | VAF 189/770 reads (25%) | SIFT tolerated (0.27); PolyPhen benign (0.017); catalogued as rs1474490422; called by muse, mutect2, varscan2
- PLEKHG7 | c.940-1G>T p.X314_splice | Splice Site (SNP) | VAF 51/213 reads (24%) | catalogued as rs1298656544; called by muse, mutect2, varscan2
- PPFIBP1 | c.2053G>T p.D685Y (on ENST00000318304 / NM_177444.3; = p.D679Y on NM_003622.4) | Missense Mutation (SNP) | VAF 163/457 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57289758; called by muse, mutect2, varscan2
- PRSS2 | c.534G>T p.K178N | Missense Mutation (SNP) | VAF 116/786 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.14); catalogued as rs1237390110, COSV52105683; called by muse, mutect2, varscan2
- SLC2A3 | c.1181G>T p.S394I | Missense Mutation (SNP) | VAF 222/720 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV50003828; called by muse, mutect2, varscan2
- TMEM121B | c.1676C>T p.S559L | Missense Mutation (SNP) | VAF 182/537 reads (34%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.579); catalogued as rs780517672, COSV104403509; called by muse, mutect2, varscan2
- TMX2 | c.320G>T p.R107L | Missense Mutation (SNP) | VAF 213/589 reads (36%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.911); catalogued as rs1180213286; called by muse, mutect2, varscan2
- UEVLD | c.524C>A p.A175E | Missense Mutation (SNP) | VAF 19/434 reads (4%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs1380462144; called by muse, mutect2
- CACNA1F | c.1342C>A p.R448S | Missense Mutation (SNP) | VAF 184/630 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- DNAAF6 | c.458C>A p.P153H | Missense Mutation (SNP) | VAF 99/359 reads (28%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- EFHD1 | c.303-3C>A | Splice Region (SNP) | VAF 112/649 reads (17%) | called by muse, mutect2, varscan2
- GSAP | c.151G>A p.V51I | Missense Mutation (SNP) | VAF 66/150 reads (44%) | SIFT tolerated (0.46); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IL1RL1 | c.913G>T p.A305S | Missense Mutation (SNP) | VAF 30/1119 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); called by muse, mutect2
- KAT6B | c.1414C>A p.Q472K | Missense Mutation (SNP) | VAF 50/1139 reads (4%) | SIFT tolerated (0.47); PolyPhen benign (0.01); called by muse, mutect2
- LY6G5C | c.347G>T p.G116V (on ENST00000375863; = p.G41V on NM_025262.3) | Missense Mutation (SNP) | VAF 15/485 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- MCM4 | c.1063C>T p.Q355* | Nonsense Mutation (SNP) | VAF 30/816 reads (4%) | called by muse, mutect2
- NBEAL1 | c.1095C>A p.C365* | Nonsense Mutation (SNP) | VAF 169/532 reads (32%) | called by muse, mutect2, varscan2
- NBEAL2 | c.1068C>A p.D356E | Missense Mutation (SNP) | VAF 24/512 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- NDRG3 | c.459G>T p.E153D (on ENST00000349004 / NM_032013.4; = p.E141D on NM_022477.4) | Missense Mutation (SNP) | VAF 108/703 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- NKIRAS2 | c.15C>A p.C5* | Nonsense Mutation (SNP) | VAF 118/532 reads (22%) | called by muse, mutect2, varscan2
- PLA2G6 | c.1786C>A p.L596I | Missense Mutation (SNP) | VAF 52/972 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SELL | c.1079G>T p.G360V (on ENST00000650983; = p.G347V on NM_000655.5) | Missense Mutation (SNP) | VAF 162/464 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SP100 | c.2363G>T p.C788F | Missense Mutation (SNP) | VAF 47/663 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.717); called by muse, mutect2
- ZNF705E | c.859C>A p.L287I | Missense Mutation (SNP) | VAF 105/758 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- CAPN11 | c.462G>T p.L154= | Silent (SNP) | VAF 197/584 reads (34%) | called by muse, mutect2, varscan2
- DDX54 | c.1008G>T p.R336= | Silent (SNP) | VAF 235/607 reads (39%) | called by muse, mutect2, varscan2
- ILDR2 | c.1728C>T p.A576= | Silent (SNP) | VAF 172/510 reads (34%) | called by muse, mutect2, varscan2
- KRT33B | c.747G>A p.T249= | Silent (SNP) | VAF 354/1596 reads (22%) | catalogued as rs745382068, COSV52442475; called by muse, mutect2, varscan2
- MOV10 | c.1119C>T p.N373= | Silent (SNP) | VAF 294/806 reads (36%) | catalogued as rs975516402; called by muse, mutect2, varscan2
- NR4A1 | c.429G>T p.T143= | Silent (SNP) | VAF 369/897 reads (41%) | catalogued as rs993949009, COSV54484113; called by muse, mutect2, varscan2
- NTF4 | c.471C>A p.G157= | Silent (SNP) | VAF 161/535 reads (30%) | called by muse, mutect2, varscan2
- SNRPF | c.246G>A p.G82= | Silent (SNP) | VAF 79/235 reads (34%) | catalogued as rs748297777; called by muse, mutect2, varscan2
- TP73 | c.129C>A p.G43= | Silent (SNP) | VAF 17/482 reads (4%) | catalogued as COSV100601377; called by muse, mutect2
- AC107023.1 | chr12:40444309 del ACA | 5'Flank (DEL) | VAF 175/630 reads (28%) | called by pindel, varscan2
- CASP10 | c.1415+8222G>T | Intron (SNP) | VAF 24/243 reads (10%) | called by muse, mutect2
- ENAM | c.535-45C>A | Intron (SNP) | VAF 18/174 reads (10%) | called by muse, varscan2
- NCR3 | c.497-141C>A | Intron (SNP) | VAF 25/637 reads (4%) | called by muse, mutect2
- NDN | c.-67G>A | 5'UTR (SNP) | VAF 103/247 reads (42%) | catalogued as COSV100086411; called by muse, mutect2, varscan2
- RASGRP2 | c.814-85C>A | Intron (SNP) | VAF 4/88 reads (5%) | called by muse, mutect2
- TNFSF15 | c.*67G>T | 3'UTR (SNP) | VAF 49/130 reads (38%) | called by muse, mutect2, varscan2
- ZNF254 | c.157+14T>C | Intron (SNP) | VAF 37/294 reads (13%) | catalogued as rs1243847126; called by muse, mutect2, varscan2
